Surgical pathology report (de-identified scan), TCGA case TCGA-DH-A66G, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-A66G-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Surgicals

Surgical Pathology Consultation / Department of Pathology

ICD-0-3

Oligodendroglioma, anaplastic
path 9451/3
Site ④ Brain, frontal lobe 71.1
CSF Brain, supratentorial NOS 71.0
JW 5/10/13

SPECIMEN(S) SUBMITTED / PROCEDURES ORDERED

A. Brain frontal tumor	A. Frozen Section Charge
B. Left frontal tumor consistent with malignant transformation	B. KI-67, Nuclear Antigen, Mib1
B. Glial Fibrill. Acid Prt	B. Isocitrate dehydrogenase 1
B. P53 Protein	B. 1P19q Malignant Glioma
Anaysis	B. 1P19q Malignant Glioma Analysis, add

CLINICAL HISTORY: This is a year old female with glioma of left frontal lobe.

DIAGNOSIS:

- A. "Brain frontal tumor", craniotomy:
Anaplastic Oligodendroglioma, WHO Grade III (see comment)
- B. "Left frontal tumor consistent with malignant transformation", craniotomy:
Anaplastic Oligodendroglioma, WHO Grade III (see comment)

COMMENT: This infiltrating glioma shows an overall histologic uniformity with hyperchromatic nuclei, perinuclear haloes and background chicken-wire vasculature. Some areas contain microgemistocytic forms. There are also areas of increased cellularity with focally increased mitotic activity, best appreciated on specimen "B". While no definitive foci of necrosis are identified in this material, there is evidence of individual tumor cell necrosis. Tumor cells are positive for mutated isocitrate dehydrogenase-1 (IDH1) and negative for p53. Ki-67 labeling index shows focally increased proliferative activity (15-20%) in highly cellular areas of specimen "B". These results support the diagnosis. The status of chromosomes 1p and 19q will be determined by fluorescence in-situ hybridization (FISH) will be reported as an addendum to this report.

GROSS DESCRIPTION: Received the following specimen(s) in the Department of Pathology, labeled with the patient's name and hospital #

- A. Brain frontal tumor
- B. Left frontal tumor consistent with malignant transformation
- A. The specimen is received fresh, designated "Brain frontal tumor" and consists of a 7.0 x 5.0 x 1.5 cm oval portion of cortical gray matter and underlying subcortical white matter. Large portions of the specimen are replaced by homogeneous white to beige tumor that merges with the gray and white matter. Large portions of the gray-white junction are obscured from the infiltrative mass. The deep surface of the specimen is fragmented and irregular. A representative portion is submitted for

[page 2 of 3]
Frozen section. Frozen section diagnosis is "Diffuse infiltrating glioma" by Dr. [REDACTED]. The frozen tissue is submitted in cassette FS1, and a portion of the remaining tumor is submitted to the Tumor Bank. Additional sections are submitted in cassettes A2-A6. [REDACTED]

B. The specimen is received fresh, designated "Left frontal tumor consistent with malignant transformation" and consists of a 2.2 x 1.5 x 1.0 cm wedge-shaped portion of beige to gray-tan soft tissue with a portion of white matter along one edge. The specimen is entirely submitted in cassettes B1 and B2. [REDACTED]
"I, or my qualified designee, performed the gross examination. I have personally reviewed the gross description and performed a microscopic examination on all referenced material. I have personally issued this report on the basis of the gross and microscopic findings."

Note: Test systems have been developed and their performance characteristics determined by [REDACTED]. Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Pathologist [REDACTED]

ADDENDUM:

CHROMOSOMES 1p / 19q FISH ANALYSIS-

A. Left frontal lobe tumor:

RESULTS

Chromosome 1p: DELETED

Chromosome 19q: DELETED

INTERPRETATION

There are co-deletions of chromosomes 1p and 19q in the tissue analyzed. Clinical studies have suggested that combined loss of chromosome 1p and 19q in oligodendroglial brain tumors may be associated with prolonged survival and enhanced response to chemotherapy (refs 1-5).

References:

1. Cairncross JG, et al. Specific genetic predictors of chemotherapeutic response and survival in patients with anaplastic oligodendrogliomas. J Natl Cancer Inst 90:1473-1479, 1998.
2. Smith JS, et al. Alterations of chromosome arms 1p and 19q as predictors of survival in oligodendrogliomas, astrocytomas, and mixed oligoastrocytomas. J Clin Oncol 18:636-45, 2000.
3. Perry A. Ancillary fish analysis for 1p and 19q status: preliminary observations in 287 gliomas and oligodendroglioma mimics. Front Biosci 8:a1-9, 2003.
4. McDonald JM, et al. The prognostic impact of histology and 1p/19q status in anaplastic oligodendroglial tumors. Cancer. 104:1468-77, 2005
5. Cairncross JG, et al. Phase III trial of chemotherapy plus radiotherapy compared with radiotherapy alone for pure and mixed anaplastic oligodendroglioma: Intergroup Radiation Therapy Oncology Group trial 9402. J Clin Oncol. 2006;24:2707-14.

Specimen [REDACTED]

Anatomic site: Brain tumor, left frontal, resection

Test description

Reference range: 1p/ 19q: Non-deleted

[page 3 of 3]
A tumor is considered to have 1p or 19q deletion when the 1p probe to 1q probe ratio (1p/1q) or the 19q probe to 19p probe ratio (19q/19p) is <0.80 . A tumor is considered to have 19q gain when the 19q/19p ratio is >1.30 . A tumor is considered to have chromosome 1 or 19 gain when the percentage of nuclei with $>$ or $=3$ signals is $>20\%$. A normal 1p/1q ratio is 0.9-1.05 and a normal 19q/19p ratio is 0.93-1.02.

The test uses two dual-probe FISH 1p36 probe combined with a control 1q probe and a 19q13.3 probe combined with a control 19p probe. Probes are specific to the minimally deleted regions of 1p (1p36) and 19q (19q13.3) to detect 1p and 19q deletion. The selection of tissue and the identification of target areas on the H&E stained slide is performed by a pathologist. The number of 1p and 19q signals in the area of interest is scored. The testing was performed and performance characteristics of this test were validated by the

It has not been cleared or approved by the FDA. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments to perform high complexity clinical laboratory testing.

Pathologist

Source: NCI Genomic Data Commons file 96f84f1b-26cc-4441-90fd-5d47d5903304 (TCGA-DH-A66G.6A01BF6C-E171-4D0A-977B-B22293ED02D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).